Somatic mutation profile of tumor specimen TCGA-XE-AAOD-01A (aliquot TCGA-XE-AAOD-01A-11D-A435-10) from TCGA case TCGA-XE-AAOD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 39.1 years (14,265 days).
Specimen TCGA-XE-AAOD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 968bee1d-11ae-49ca-9339-e3fbe4b8ecdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAOD-10A (Blood Derived Normal), aliquot TCGA-XE-AAOD-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0d1abc5-bc36-4584-82b2-6518c321ba99

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC25A5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1250375775, COSV100510445; called by muse, mutect2, varscan2
- OGT | c.3059A>G p.Y1020C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDS5A | c.2925dup p.I976Yfs*9 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- XPNPEP2 | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF425 | c.1500C>A p.C500* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ABCA3 | c.1257C>T p.A419= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs767207734; called by muse, mutect2, varscan2
- QARS1 | c.553C>T p.L185= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
